Somatic mutation profile of tumor specimen ALCH-ADV2-TTP1-A (aliquot ALCH-ADV2-TTP1-A-2-0-D-A603-36) from ALCHEMIST case ALCH-ADV2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,613 days).
Specimen ALCH-ADV2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 010527f8-401c-449a-83b5-382409149204.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADV2-NB1-A (Blood Derived Normal), aliquot ALCH-ADV2-NB1-A-1-0-D-A603-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10f29925-024d-4e60-998b-725234f418c5

The open-access MAF lists 80 somatic variants for this specimen: 53 protein-altering or splice-affecting, 15 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 15, Intron 6, Nonsense Mutation 6, Frame Shift Del 5, 5'UTR 3, In Frame Del 1, Splice Region 1, 5'Flank 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 172/750 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADGRA1 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs779430359, COSV66925424; called by muse, mutect2, varscan2
- ARHGAP9 | c.1802C>G p.S601C (on ENST00000393797 / NM_001319850.2; = p.S582C on NM_032496.4) | Missense Mutation (SNP) | VAF 29/432 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57361626; called by muse, mutect2
- CFHR4 | c.1654G>T p.G552* (on ENST00000367416 / NM_001201551.2; = p.G306* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 17/582 reads (3%) | catalogued as COSV99260428; called by muse, mutect2
- DCPS | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 22/386 reads (6%) | catalogued as rs1483080528; called by muse, mutect2
- DYNC1LI2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99263251; called by muse, mutect2
- EPM2AIP1 | c.1697G>C p.R566P | Missense Mutation (SNP) | VAF 40/561 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV51617694; called by muse, mutect2
- FPGT | c.1590G>C p.K530N | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV100907628; called by muse, mutect2
- KDM5C | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 103/440 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64763558; called by muse, mutect2, varscan2
- MTURN | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 46/790 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.97); catalogued as COSV61023222; called by muse, mutect2
- OR2L2 | c.512G>C p.R171T | Missense Mutation (SNP) | VAF 38/424 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs755473752, COSV63560714; called by muse, mutect2
- PCDHA1 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs782217299; called by muse, mutect2
- PEG3 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs771139564, COSV55628095; called by muse, mutect2
- SYNE1 | c.5788C>G p.L1930V (on ENST00000367255 / NM_182961.4; = p.L1937V on NM_033071.3) | Missense Mutation (SNP) | VAF 120/913 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55020447; called by muse, mutect2, varscan2
- TGM2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 39/574 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs776311789, COSV63932097; called by muse, mutect2
- TTC21B | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 44/726 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs775370323, COSV54630626; called by muse, mutect2
- ARHGEF28 | c.1333_1335del p.F445del | In Frame Del (DEL) | VAF 72/739 reads (10%) | called by mutect2, pindel
- ATG12 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- B3GNT4 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTNNA2 | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX3X | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- DDX60L | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- DGKZ | c.1534C>T p.R512* (on ENST00000454345 / NM_001105540.2; = p.R324* on NM_003646.4) | Nonsense Mutation (SNP) | VAF 54/360 reads (15%) | called by muse, mutect2, varscan2
- FKBP11 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.784); called by muse, mutect2
- LAMA5 | c.8875C>T p.Q2959* | Nonsense Mutation (SNP) | VAF 12/153 reads (8%) | called by muse, mutect2
- LMAN2L | c.396C>G p.I132M | Missense Mutation (SNP) | VAF 36/429 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2
- LRP5 | c.684C>T p.F228= | Splice Region (SNP) | VAF 14/382 reads (4%) | called by muse, mutect2
- MGAT4D | c.410T>C p.I137T | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MIER2 | c.795del p.D266Tfs*10 | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | called by mutect2, pindel, varscan2
- MOSMO | c.149A>G p.H50R | Missense Mutation (SNP) | VAF 61/555 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MRGPRD | c.582G>T p.M194I | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, varscan2
- NKAPL | c.486T>G p.H162Q | Missense Mutation (SNP) | VAF 43/551 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.021); called by muse, mutect2
- NPAS4 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 18/482 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); called by muse, mutect2
- NRIP1 | c.3337G>C p.E1113Q | Missense Mutation (SNP) | VAF 11/306 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- PKHD1 | c.11038T>C p.S3680P | Missense Mutation (SNP) | VAF 60/638 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.361); called by muse, mutect2
- PLEKHA4 | c.471_474del p.D158Mfs*25 | Frame Shift Del (DEL) | VAF 17/127 reads (13%) | called by mutect2, pindel, varscan2
- PRKCQ | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 22/469 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTGDS | c.128G>T p.W43L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- RNF34 | c.29del p.A10Vfs*7 | Frame Shift Del (DEL) | VAF 58/339 reads (17%) | called by mutect2, pindel, varscan2
- RNF40 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 24/349 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2
- SCFD2 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
- SETD2 | c.2975del p.T992Ifs*14 | Frame Shift Del (DEL) | VAF 49/257 reads (19%) | called by mutect2, pindel, varscan2
- SHLD2 | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- SLC29A1 | c.1215C>G p.F405L | Missense Mutation (SNP) | VAF 48/656 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.211); called by muse, mutect2
- SPRED1 | c.295T>G p.F99V | Missense Mutation (SNP) | VAF 81/778 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STAT4 | c.1686G>T p.K562N | Missense Mutation (SNP) | VAF 48/287 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SYDE2 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.14046G>C p.L4682F (on ENST00000367255 / NM_182961.4; = p.L4611F on NM_033071.3) | Missense Mutation (SNP) | VAF 38/908 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- TBL3 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- TUT4 | c.3362C>T p.S1121L | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- ULK4 | c.1441del p.A481Pfs*6 | Frame Shift Del (DEL) | VAF 67/435 reads (15%) | called by mutect2, pindel, varscan2
- VPS9D1 | c.1112C>G p.S371C | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- YEATS2 | c.3115T>G p.S1039A | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- APC2 | c.1464C>T p.R488= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs149237523; called by muse, mutect2, varscan2
- ATP4A | c.1464C>A p.V488= | Silent (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
- CTNNAL1 | c.72C>T p.F24= | Silent (SNP) | VAF 15/233 reads (6%) | catalogued as rs1166231163, COSV57705086; called by muse, mutect2
- FAM216B | c.24A>G p.Q8= | Silent (SNP) | VAF 50/261 reads (19%) | called by muse, mutect2, varscan2
- FARP1 | c.885G>C p.L295= | Silent (SNP) | VAF 12/352 reads (3%) | catalogued as COSV60341284; called by muse, mutect2
- FLVCR2 | c.30G>A p.E10= | Silent (SNP) | VAF 40/472 reads (8%) | called by muse, mutect2
- FSCN1 | c.366C>T p.F122= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as rs1459493530, COSV61018527; called by muse, mutect2
- GDF7 | c.633C>T p.F211= | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- GON4L | c.2130C>G p.T710= | Silent (SNP) | VAF 100/1196 reads (8%) | called by muse, mutect2
- KRBOX1 | c.63T>C p.A21= | Silent (SNP) | VAF 27/234 reads (12%) | called by muse, mutect2, varscan2
- MAP4 | c.1374G>C p.V458= | Silent (SNP) | VAF 21/380 reads (6%) | called by muse, mutect2
- PIM1 | c.168C>A p.I56= | Silent (SNP) | VAF 16/294 reads (5%) | catalogued as COSV65166176; called by muse, mutect2
- RP1 | c.5242C>T p.L1748= | Silent (SNP) | VAF 19/442 reads (4%) | called by muse, mutect2
- SAMSN1 | c.516G>A p.T172= | Silent (SNP) | VAF 85/391 reads (22%) | catalogued as rs745867626, COSV53467189; called by muse, mutect2, varscan2
- ZFHX2 | c.6786G>A p.L2262= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- AIMP2 | c.-19C>A | 5'UTR (SNP) | VAF 15/292 reads (5%) | called by muse, mutect2
- ALDH6A1 | c.428-18C>T | Intron (SNP) | VAF 66/380 reads (17%) | catalogued as rs896524780; called by muse, mutect2, varscan2
- CARMIL3 | chr14:24049294 G>C | 5'Flank (SNP) | VAF 35/530 reads (7%) | called by muse, mutect2
- CLCN6 | c.2529+147G>A | Intron (SNP) | VAF 37/186 reads (20%) | called by muse, mutect2, varscan2
- KRT6A | c.-14C>T | 5'UTR (SNP) | VAF 80/794 reads (10%) | called by muse, mutect2, varscan2
- LIMCH1 | c.935+7403G>A | Intron (SNP) | VAF 96/966 reads (10%) | called by muse, mutect2
- LRRC37B | c.2124-4634C>G | Intron (SNP) | VAF 20/148 reads (14%) | catalogued as rs750854712; called by muse, mutect2, varscan2
- ORC6 | c.*59G>A | 3'UTR (SNP) | VAF 52/775 reads (7%) | called by muse, mutect2
- RTF2 | c.646+12C>T | Intron (SNP) | VAF 14/328 reads (4%) | called by muse, mutect2
- SNORD114-6 | n.57G>T | RNA (SNP) | VAF 105/447 reads (23%) | called by muse, mutect2, varscan2
- SV2C | c.581-21203C>T | Intron (SNP) | VAF 173/858 reads (20%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-3C>T | 5'UTR (SNP) | VAF 32/163 reads (20%) | catalogued as rs776687705, COSV56552223; called by muse, mutect2, varscan2
